Gene-level copy-number profile of tumor specimen C3L-05598-03 from CPTAC case C3L-05598, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.1 years (27,423 days).
Specimen C3L-05598-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd5eae30-6b1e-4a2e-8579-cb1df768bfff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05598-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/49494f46-f085-4293-b26d-058afdeebd0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 7,424; copy number 2: 49,047; copy number 3: 1,765; copy number 4: 32; copy number 5: 125.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 125 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:44,216,926–44,380,179, 11 genes, copy number 5: MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1.
- chr9:72,107,818–72,874,135, 13 genes, copy number 5: BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474.
- chr9:73,151,865–73,476,073, 2 genes, copy number 5: ANXA1, DPP3P2.
- chr9:77,176,760–78,031,811, 7 genes, copy number 5: VPS13A-AS1, VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P, GNAQ.
- chr9:81,583,683–81,689,547, 1 gene, copy number 5: TLE1.
- chr9:81,885,496–84,657,077, 46 genes, copy number 5: RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, RPS6P12, RASEF, RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1, GKAP1, AL354733.1, AL354733.2, KIF27, C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2, SLC28A3, AL356134.1, AL157886.1, AL354692.1.
- chr9:85,492,579–85,849,542, 6 genes, copy number 5: STK33P1, AGTPBP1, AL353743.4, AL157882.1, AL353743.2, AL353743.1.
- chr9:86,220,265–87,837,225, 28 genes, copy number 5: C9orf153, AL137849.1, RN7SKP264, ISCA1, TUT7, AL353678.1, AL158828.1, RNU2-36P, AL353613.1, LINC02834, GAS1, GAS1RR, AL513318.1, CDC20P1, NFYCP2, LINC02872, AL136367.1, AL353752.1, DAPK1, AL161787.1, DAPK1-IT1, CTSL, AL160279.1, CTSL3P, AL772337.4, FBP2P1, ELF2P3, NPAP1P7.
- chr9:90,158,028–90,433,566, 4 genes, copy number 5: AL353649.1, OR7E31P, OR7E116P, LINC01508.
- chr9:93,058,688–93,346,414, 7 genes, copy number 5: SUSD3, AL451065.1, CARD19, NINJ1, AL390760.1, WNK2, C9orf129.

Autosomal genes at a single copy (total copy number 1): 5,080. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
